Somatic mutation profile of tumor specimen TCGA-73-7498-01A (aliquot TCGA-73-7498-01A-12D-2184-08) from TCGA case TCGA-73-7498, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 58.9 years (21,527 days).
Specimen TCGA-73-7498-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0f91091-0153-488d-85b7-4544a0e22c1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-73-7498-10A (Blood Derived Normal), aliquot TCGA-73-7498-10A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9c46dd7-be43-4e5a-b1d0-c7279d6b6d54

The open-access MAF lists 124 somatic variants for this specimen: 88 protein-altering or splice-affecting, 34 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 34, Frame Shift Del 6, Nonsense Mutation 3, Frame Shift Ins 1, 5'UTR 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AATK | c.2760C>A p.F920L (on ENST00000326724 / NM_001080395.3; = p.F817L on NM_004920.2) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV58369520, COSV58373991; called by muse, mutect2, varscan2
- AMMECR1 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.202); catalogued as COSV53320866; called by muse, mutect2, varscan2
- ATP1A1 | c.2236G>A p.A746T | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV55194717; called by muse, mutect2, varscan2
- ATP2B2 | c.1403A>C p.N468T (on ENST00000352432; = p.N434T on NM_001683.5) | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59508668; called by muse, mutect2, varscan2
- ATXN3L | c.673G>C p.D225H | Missense Mutation (SNP) | VAF 116/350 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV66076343; called by muse, mutect2, varscan2
- BBS9 | c.1206G>T p.W402C | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.77); catalogued as COSV54190228; called by muse, mutect2, varscan2
- CAVIN1 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV63812883; called by muse, mutect2, varscan2
- CCDC51 | c.416G>C p.R139P | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56491970, COSV56494760, COSV99603362; called by muse, mutect2, varscan2
- CCIN | c.850C>T p.L284F | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs762028043, COSV58725893; called by muse, mutect2, varscan2
- CELA3A | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51587446; called by muse, mutect2, varscan2
- CLDN2 | c.16C>A p.L6I | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV61021406; called by muse, mutect2, varscan2
- CPT1A | c.266G>C p.R89P | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.264); catalogued as COSV55762003, COSV99680738; called by muse, mutect2, varscan2
- CR1L | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 73/215 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.048); catalogued as rs774796966, COSV54332098; called by muse, mutect2, varscan2
- CYP20A1 | c.1324A>G p.T442A | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV61910550; called by muse, mutect2, varscan2
- DMBT1 | c.2366G>C p.G789A | Missense Mutation (SNP) | VAF 67/263 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as COSV57566026; called by muse, mutect2, varscan2
- DNAJA4 | c.395del p.N132Mfs*2 (on ENST00000343789; = p.N161Mfs*2 on NM_018602.3) | Frame Shift Del (DEL) | VAF 30/115 reads (26%) | catalogued as COSV59425422; called by mutect2, pindel, varscan2
- DNAJC5B | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52540826; called by muse, mutect2, varscan2
- DRD5 | c.1372G>T p.D458Y | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100431607, COSV58580829; called by muse, mutect2, varscan2
- DRP2 | c.2136G>T p.W712C | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV65812108; called by muse, mutect2
- DSCAML1 | c.2390C>A p.P797H (on ENST00000321322; = p.P737H on NM_020693.4) | Missense Mutation (SNP) | VAF 59/208 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV58404333; called by muse, mutect2, varscan2
- DST | c.20393G>A p.C6798Y (on ENST00000361203 / NM_001374722.1; = p.C4495Y on NM_015548.5) | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55044489; called by muse, mutect2, varscan2
- EBF3 | c.1007G>T p.C336F (on ENST00000355311 / NM_001375392.1; = p.C327F on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62482687; called by muse, mutect2, varscan2
- ETV6 | c.1003A>G p.I335V | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.685); catalogued as COSV67154723; called by muse, mutect2, varscan2
- FBXO43 | c.1528C>G p.L510V | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV71054721, COSV71055699; called by muse, mutect2, varscan2
- GABRA4 | c.1052C>G p.A351G | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as COSV51926990; called by muse, mutect2, varscan2
- GOLGA6B | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as rs778248868, COSV69770668; called by muse, mutect2, varscan2
- GSDME | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs770265619, COSV61653088; called by muse, mutect2, varscan2
- HOOK2 | c.1922G>T p.R641L | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.793); catalogued as rs752054044, COSV53403219, COSV53404415; called by muse, mutect2, varscan2
- HRNR | c.1915C>A p.H639N | Missense Mutation (SNP) | VAF 97/772 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV64263532; called by muse, mutect2, varscan2
- HSP90AB1 | c.767A>T p.D256V | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100807195, COSV62336504; called by muse, mutect2, varscan2
- HUWE1 | c.9209G>T p.R3070L | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53366358; called by muse, mutect2, varscan2
- HUWE1 | c.9022G>T p.V3008L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.956); catalogued as COSV53366375; called by muse, mutect2, varscan2
- IL4R | c.146A>G p.N49S | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs747063458, COSV50183785; called by muse, mutect2
- KCNT2 | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 43/211 reads (20%) | catalogued as rs1442741716, COSV54112939; called by muse, mutect2, varscan2
- KEAP1 | c.653A>T p.E218V | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as COSV50276208; called by muse, mutect2, varscan2
- KLHL38 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs376622136; called by muse, mutect2, varscan2
- KRT10 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1284338985, COSV54091764; called by muse, mutect2, varscan2
- MBL2 | c.375G>A p.W125* | Nonsense Mutation (SNP) | VAF 37/109 reads (34%) | catalogued as COSV64759548; called by muse, mutect2, varscan2
- MCF2L2 | c.1844G>A p.G615E | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV58477219; called by muse, mutect2
- NECTIN4 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.572); catalogued as COSV63514158; called by muse, mutect2, varscan2
- NR3C1 | c.905G>T p.C302F | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51546990; called by muse, mutect2, varscan2
- NUP214 | c.6217T>G p.F2073V | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63913582; called by muse, varscan2
- OAS2 | c.652C>A p.P218T | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV60804786; called by muse, mutect2, varscan2
- OR1S1 | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 69/270 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58708984; called by muse, mutect2, varscan2
- OR2G6 | c.541G>T p.V181L | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV58576051; called by muse, mutect2, varscan2
- OR4A5 | c.712A>T p.S238C | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); catalogued as COSV60525057; called by muse, mutect2, varscan2
- PAX6 | c.1069A>T p.M357L | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV53795931; called by muse, mutect2, varscan2
- PCDH18 | c.1733G>T p.G578V | Missense Mutation (SNP) | VAF 73/250 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV61272661; called by muse, mutect2, varscan2
- PHEX | c.1187C>T p.T396I | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV65079582; called by muse, mutect2, varscan2
- POGZ | c.2887G>T p.G963C | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.243); catalogued as COSV51853571, COSV99305087; called by mutect2, varscan2
- POLA1 | c.1819G>T p.V607L | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV66891369; called by muse, mutect2, varscan2
- RBM10 | c.1161-2A>T p.X387_splice | Splice Site (SNP) | VAF 8/50 reads (16%) | catalogued as COSV61310849; called by muse, mutect2, varscan2
- REN | c.1070G>T p.S357I | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.182); catalogued as COSV65818536; called by muse, mutect2, varscan2
- RGMA | c.260G>T p.R87L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV61237283; called by muse, mutect2, varscan2
- RITA1 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV58376458; called by muse, mutect2, varscan2
- RNF26 | c.523G>T p.G175W | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV60991703; called by muse, mutect2, varscan2
- RYR2 | c.8227T>A p.Y2743N | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV63718949; called by muse, mutect2, varscan2
- SEMG2 | c.86A>C p.K29T | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65648057; called by muse, mutect2, varscan2
- SETBP1 | c.2696T>C p.L899P | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV56338924; called by muse, varscan2
- SGSH | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs760096011, CM128247, COSV58340064; called by muse, mutect2, varscan2
- SIGLECL1 | c.194G>A p.W65* | Nonsense Mutation (SNP) | VAF 24/51 reads (47%) | catalogued as COSV57062128; called by muse, mutect2, varscan2
- SLC13A2 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs782087379, COSV58996941; called by muse, mutect2, varscan2
- SLC45A2 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 120/359 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV56875980; called by muse, mutect2, varscan2
- SMARCD1 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.277); catalogued as COSV57320547; called by muse, mutect2, varscan2
- SPRR3 | c.391A>C p.I131L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as COSV54881693; called by muse, mutect2, varscan2
- SYT10 | c.421C>G p.P141A | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.53); catalogued as COSV57346261; called by muse, mutect2, varscan2
- TMEM132B | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs774182915, COSV54773076; called by muse, mutect2, varscan2
- TOGARAM1 | c.1510G>C p.E504Q | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.648); catalogued as COSV61889512; called by muse, mutect2, varscan2
- TPO | c.969C>G p.F323L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV61112567; called by muse, mutect2, varscan2
- TPSD1 | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.663); catalogued as rs1372765594, COSV52979017; called by muse, mutect2
- USH2A | c.6815C>T p.T2272M | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs776972526, CM1410600, COSV56448732; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP29 | c.1563G>T p.L521F | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.828); catalogued as COSV54147265; called by muse, mutect2, varscan2
- WWC3 | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV66508460; called by muse, mutect2, varscan2
- ZFHX4 | c.4996G>T p.D1666Y | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV50797840, COSV51499718; called by muse, mutect2, varscan2
- ZFP30 | c.1384G>C p.G462R | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63623221; called by muse, mutect2, varscan2
- ZFP36L1 | c.902A>T p.D301V | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60547433; called by muse, mutect2, varscan2
- ZHX2 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 52/268 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as rs1191062135, COSV58718146; called by muse, mutect2, varscan2
- ZMAT4 | c.664C>A p.H222N | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV52716935; called by muse, mutect2, varscan2
- ZNF81 | c.767G>C p.S256T | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV58578876; called by muse, mutect2, varscan2
- CHD5 | c.4317G>T p.W1439C | Missense Mutation (SNP) | VAF 2/12 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CNGA1 | c.843_844delinsACA p.F281Lfs*39 | Frame Shift Ins (INS) | VAF 21/98 reads (21%) | called by pindel, varscan2*
- ELOVL6 | c.687del p.Q230Rfs*29 | Frame Shift Del (DEL) | VAF 55/191 reads (29%) | called by mutect2, pindel, varscan2
- IGLC2 | c.260G>A p.C87Y | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SETBP1 | c.2614_2623del p.G872Tfs*86 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by pindel, varscan2
- STAT3 | c.1232del p.L411* | Frame Shift Del (DEL) | VAF 25/118 reads (21%) | called by mutect2, pindel, varscan2
- STK11 | c.157del p.D53Tfs*11 | Frame Shift Del (DEL) | VAF 26/88 reads (30%) | called by mutect2, pindel, varscan2
- UTP20 | c.309del p.Y104Ifs*28 | Frame Shift Del (DEL) | VAF 40/139 reads (29%) | called by mutect2, pindel, varscan2
- ABCA13 | c.14727G>C p.A4909= | Silent (SNP) | VAF 33/161 reads (20%) | catalogued as COSV68951328; called by muse, mutect2, varscan2
- ABL1 | c.3153C>T p.A1051= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV59342760; called by muse, mutect2, varscan2
- ADAM33 | c.372C>A p.P124= | Silent (SNP) | VAF 4/59 reads (7%) | catalogued as rs1033626972, COSV62933407, COSV62937172; called by muse, mutect2
- AP4M1 | c.186C>T p.S62= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as rs745829752, COSV57999458; called by muse, mutect2
- C8orf76 | c.72G>A p.R24= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs1277564060, COSV52692273; called by muse, mutect2, varscan2
- DCAF8L1 | c.57G>T p.L19= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV71595566; called by muse, mutect2, varscan2
- DST | c.1104C>T p.A368= | Silent (SNP) | VAF 63/153 reads (41%) | catalogued as COSV55044505; called by muse, mutect2, varscan2
- FGF4 | c.474G>A p.K158= | Silent (SNP) | VAF 12/224 reads (5%) | catalogued as COSV51450959; called by muse, mutect2
- FITM2 | c.585G>T p.L195= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV67679525; called by muse, mutect2, varscan2
- GABRA4 | c.1053C>G p.A351= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV51935948, COSV99973798; called by muse, mutect2, varscan2
- HK3 | c.594G>T p.V198= | Silent (SNP) | VAF 130/498 reads (26%) | catalogued as COSV52845392; called by muse, mutect2, varscan2
- HOXA6 | c.651C>T p.I217= | Silent (SNP) | VAF 53/161 reads (33%) | catalogued as rs781019309, COSV56075144; called by muse, mutect2, varscan2
- HUWE1 | c.5028C>A p.R1676= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV53366394; called by muse, mutect2, varscan2
- KDR | c.2979A>G p.E993= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV99817150; called by muse, mutect2, varscan2
- LCT | c.4443G>T p.L1481= | Silent (SNP) | VAF 25/110 reads (23%) | catalogued as rs770849268, COSV51558651; called by muse, mutect2, varscan2
- OR2G3 | c.828C>A p.L276= | Silent (SNP) | VAF 33/112 reads (29%) | catalogued as COSV60682708, COSV60683478; called by muse, mutect2, varscan2
- PCDH15 | c.4722C>A p.T1574= (on ENST00000644397 / NM_001354429.2; = p.T1516= on NM_001142771.2) | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV64746191; called by muse, mutect2, varscan2
- PCDHA12 | c.1683C>T p.N561= | Silent (SNP) | VAF 65/217 reads (30%) | catalogued as COSV56525703; called by muse, mutect2, varscan2
- PCDHB14 | c.1986G>C p.L662= | Silent (SNP) | VAF 39/132 reads (30%) | catalogued as COSV53391699; called by muse, mutect2, varscan2
- PCDHB2 | c.1539C>A p.G513= | Silent (SNP) | VAF 23/232 reads (10%) | catalogued as COSV50639154; called by muse, mutect2
- PLCB1 | c.1821C>A p.S607= | Silent (SNP) | VAF 50/117 reads (43%) | catalogued as COSV62071273; called by muse, mutect2, varscan2
- POMGNT2 | c.432C>G p.P144= | Silent (SNP) | VAF 15/142 reads (11%) | catalogued as COSV60954918; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.924G>T p.L308= (on ENST00000352766; = p.L185= on NM_181334.5) | Silent (SNP) | VAF 45/124 reads (36%) | catalogued as COSV61237451; called by muse, mutect2, varscan2
- ROBO2 | c.3366G>T p.L1122= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as COSV59943966; called by muse, mutect2, varscan2
- ROR2 | c.1539G>T p.A513= | Silent (SNP) | VAF 48/143 reads (34%) | catalogued as COSV65218414, COSV65224085; called by muse, mutect2, varscan2
- RPRM | c.39C>A p.G13= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV57989282; called by muse, mutect2, varscan2
- SEC23IP | c.861T>G p.P287= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV64833387; called by muse, mutect2, varscan2
- SOX10 | c.529C>A p.R177= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV62806470, COSV62807596; called by muse, mutect2, varscan2
- SYCP2 | c.744A>T p.A248= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs1159951529, COSV62772435; called by muse, mutect2, varscan2
- TECTA | c.1059G>A p.L353= | Silent (SNP) | VAF 10/165 reads (6%) | catalogued as COSV50824430; called by muse, mutect2
- TMEM102 | c.999C>T p.S333= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV53441457; called by muse, mutect2, varscan2
- TNRC6A | c.5631C>T p.S1877= | Silent (SNP) | VAF 65/221 reads (29%) | catalogued as COSV59370877; called by muse, mutect2, varscan2
- TRPC6 | c.415T>C p.L139= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV60261936; called by muse, mutect2, varscan2
- WWC3 | c.2076A>G p.S692= | Silent (SNP) | VAF 36/141 reads (26%) | catalogued as COSV66508471; called by muse, mutect2, varscan2
- STAG2 | c.3467+149A>G | Intron (SNP) | VAF 17/72 reads (24%) | catalogued as COSV99492812; called by muse, mutect2, varscan2
- TREML2 | c.-63C>T | 5'UTR (SNP) | VAF 29/69 reads (42%) | catalogued as rs1230773727, COSV101530158; called by muse, mutect2, varscan2
